Somatic mutation profile of tumor specimen C3N-02929-01 (aliquot CPT0184740007) from CPTAC case C3N-02929, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 58.1 years (21,205 days).
Specimen C3N-02929-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4424e04-0275-4b75-9336-d31a9a48dbc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02929-31 (Blood Derived Normal), aliquot CPT0184800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82b05964-310c-48c4-98a1-cc378d183408

The open-access MAF lists 63 somatic variants for this specimen: 36 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, 5'UTR 4, Intron 3, 3'UTR 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 162/627 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AKAP8 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 76/579 reads (13%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs569129129; called by muse, mutect2, varscan2
- CCDC93 | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs753072596; called by muse, mutect2, varscan2
- CETN1 | c.198G>C p.K66N | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV59121357; called by muse, mutect2, varscan2
- CPM | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as rs371647855; called by muse, mutect2
- DLGAP2 | c.2916C>A p.N972K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs368740931; called by muse, mutect2, varscan2
- FLNC | c.6860C>T p.T2287M | Missense Mutation (SNP) | VAF 17/504 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs1434865362, COSV57956782; called by muse, mutect2
- FRY | c.8208C>G p.I2736M | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.228); catalogued as COSV66580253; called by muse, mutect2, varscan2
- GULP1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63070666; called by muse, mutect2, varscan2
- JAKMIP3 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs908104354; called by muse, mutect2
- KRTAP10-8 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs782354016; called by muse, mutect2, varscan2
- LAMA5 | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 33/238 reads (14%) | catalogued as rs1000857651; called by muse, mutect2, varscan2
- RIPOR2 | c.1181A>G p.D394G | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV99429102; called by muse, mutect2
- SUSD1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV62584338; called by muse, mutect2
- TCF7L1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1182158493; called by muse, mutect2
- TCN1 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57252987; called by muse, mutect2
- TNRC6B | c.1481A>G p.N494S | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs751692063, COSV57293470; called by muse, mutect2, varscan2
- ASXL2 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 29/355 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- ATP1B4 | c.1040G>T p.G347V (on ENST00000218008 / NM_001142447.3; = p.G343V on NM_012069.5) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH7 | c.149T>G p.V50G | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- CPLANE1 | c.8850A>T p.K2950N | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYP11B1 | c.860C>A p.T287N | Missense Mutation (SNP) | VAF 55/597 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- F7 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 48/323 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GABRB1 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- HECTD4 | c.2936C>A p.S979Y | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- IQCK | c.430A>G p.M144V | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IRX4 | c.731A>C p.N244T | Missense Mutation (SNP) | VAF 15/241 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2
- JPH2 | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 18/631 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- MUC13 | c.1253-1G>C p.X418_splice | Splice Site (SNP) | VAF 22/103 reads (21%) | called by muse, varscan2
- NUDT21 | c.459del p.F153Lfs*42 | Frame Shift Del (DEL) | VAF 24/189 reads (13%) | called by mutect2, pindel, varscan2
- OR2L3 | c.831C>A p.Y277* | Nonsense Mutation (SNP) | VAF 14/454 reads (3%) | called by muse, mutect2
- OR2V1 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- PHACTR3 | c.1297A>T p.I433F | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SIK3 | c.846-1G>T p.X282_splice (on ENST00000445177 / NM_001366686.2; = p.X289_splice on NM_025164.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- TFCP2 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ULBP2 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 51/338 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- CYP2D7 | c.558C>A p.I186= | Silent (SNP) | VAF 23/322 reads (7%) | catalogued as rs754964138; called by muse, mutect2
- FAM163A | c.165G>A p.T55= | Silent (SNP) | VAF 75/850 reads (9%) | catalogued as rs1375668115, COSV100523077, COSV59202324; called by muse, mutect2
- GABRA5 | c.1167G>A p.P389= | Silent (SNP) | VAF 46/246 reads (19%) | catalogued as rs776414656, COSV59482736; called by muse, mutect2, varscan2
- GPR39 | c.708C>T p.L236= | Silent (SNP) | VAF 31/294 reads (11%) | catalogued as rs1303124619; called by muse, mutect2, varscan2
- LAMA5 | c.1815C>T p.C605= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs748293998; called by muse, mutect2, varscan2
- MTMR11 | c.21C>T p.G7= | Silent (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- MUC1 | c.3102C>T p.S1034= (on ENST00000611571 / NM_001371720.1; = p.S247= on NM_001204285.2) | Silent (SNP) | VAF 72/621 reads (12%) | catalogued as rs763918894; called by muse, mutect2, varscan2
- MUC12 | c.636T>A p.L212= (on ENST00000379442; = p.L69= on NM_001164462.1) | Silent (SNP) | VAF 18/207 reads (9%) | called by muse, mutect2
- NDUFS4 | c.60G>A p.V20= | Silent (SNP) | VAF 66/1106 reads (6%) | catalogued as rs770122859; called by muse, mutect2
- NRXN1 | c.1545C>T p.G515= | Silent (SNP) | VAF 32/321 reads (10%) | catalogued as rs745993564, COSV58444668; called by muse, mutect2
- OR2AK2 | c.102C>T p.L34= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- PCDH15 | c.1674C>A p.I558= | Silent (SNP) | VAF 37/249 reads (15%) | catalogued as COSV57411744; called by muse, mutect2, varscan2
- PDCD10 | c.450G>A p.K150= | Silent (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- PIK3IP1 | c.540C>T p.I180= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- TDRD12 | c.2614C>T p.L872= (on ENST00000444215; = p.L877= on NM_001366102.1) | Silent (SNP) | VAF 26/157 reads (17%) | called by muse, mutect2, varscan2
- TIE1 | c.2292G>A p.A764= | Silent (SNP) | VAF 52/369 reads (14%) | catalogued as rs1375428745; called by muse, mutect2, varscan2
- AC011487.2 | n.1104C>G | RNA (SNP) | VAF 28/240 reads (12%) | called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs73150876; called by muse, varscan2
- CEP41 | c.*3227G>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2, varscan2
- DMAP1 | c.394-45G>C | Intron (SNP) | VAF 101/471 reads (21%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.*37G>A | 3'UTR (SNP) | VAF 26/327 reads (8%) | called by muse, mutect2
- KCNK10 | c.38-7200T>C | Intron (SNP) | VAF 25/277 reads (9%) | called by muse, mutect2
- MLX | c.*1203C>T | 3'UTR (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- POLL | c.-354A>G | 5'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- TRGV5 | c.-18G>C | 5'UTR (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- TVP23C | c.-26G>A | 5'UTR (SNP) | VAF 19/334 reads (6%) | called by muse, mutect2
- VAMP3 | c.-82C>T | 5'UTR (SNP) | VAF 42/370 reads (11%) | called by muse, mutect2, varscan2
